Somatic mutation profile of tumor specimen TCGA-EM-A2CT-01A (aliquot TCGA-EM-A2CT-01A-11D-A17V-08) from TCGA case TCGA-EM-A2CT, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 20.7 years (7,558 days).
Specimen TCGA-EM-A2CT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7281a29-0de8-47d6-8f11-9be1f97f5e28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2CT-10A (Blood Derived Normal), aliquot TCGA-EM-A2CT-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c260e57b-4fd9-461b-bf22-9bc436d2cdb2

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 60/174 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.5718A>C p.R1906S | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58617970; called by muse, mutect2, varscan2
- KRTAP4-12 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as rs746737044, COSV67457807; called by muse, mutect2, varscan2
- WDR7 | c.3831+2T>C p.X1277_splice | Splice Site (SNP) | VAF 10/114 reads (9%) | catalogued as COSV54351206; called by muse, mutect2
